Somatic mutation profile of cancer-model specimen HCM-CSHL-1097-C18-85A (3D Organoid, passage 5; aliquot HCM-CSHL-1097-C18-85A-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1097-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.3 years (21,277 days).
Specimen HCM-CSHL-1097-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c6baf0-9d62-4a94-b7d1-62069dd1f38f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1097-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-1097-C18-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98861a82-6ea4-4d4c-84ac-6b9efbc73b85

The open-access MAF lists 132 somatic variants for this specimen: 103 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 23, Nonsense Mutation 9, Intron 3, In Frame Del 3, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.8329C>T p.R2777* | Nonsense Mutation (SNP) | VAF 228/512 reads (45%) | catalogued as rs886039330, CM096540; ClinVar: pathogenic; called by muse, varscan2
- IDH2 | c.516G>C p.R172S | Missense Mutation (SNP) | VAF 278/556 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1057519736, COSV57468772, COSV57468910, COSV57481094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 167/167 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 124/290 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as CM126689, COSV55903618; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 152/349 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC9A3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 178/337 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs869312806, CM1512085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 262/563 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1193496273, COSV60630500; called by muse, mutect2, varscan2
- APBA2 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 191/418 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375339761; called by muse, mutect2, varscan2
- APC | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 350/350 reads (100%) | catalogued as CM940071, COSV57325166, COSV57330894, COSV57378134; called by muse, mutect2, varscan2
- BCOR | c.1005del p.S336Rfs*42 | Frame Shift Del (DEL) | VAF 392/1094 reads (36%) | catalogued as CD093233; called by pindel, varscan2
- CAPN12 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 388/776 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs148346184; called by muse, mutect2
- CCKBR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 333/670 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58098388; called by muse, mutect2, varscan2
- CD1D | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1245473930, COSV63808690; called by muse, mutect2, varscan2
- COL4A1 | c.2458+1G>T p.X820_splice | Splice Site (SNP) | VAF 169/302 reads (56%) | catalogued as CS152951; called by muse, mutect2, varscan2
- COL6A3 | c.5635G>A p.G1879S | Missense Mutation (SNP) | VAF 345/711 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs760603443, COSV55080149; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- CSMD3 | c.10373C>A p.T3458N (on ENST00000297405 / NM_001363185.1; = p.T3289N on NM_052900.3) | Missense Mutation (SNP) | VAF 153/305 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs776572675, COSV52099285; called by muse, mutect2, varscan2
- DNAH5 | c.7943C>T p.A2648V | Missense Mutation (SNP) | VAF 188/402 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs201939338; ClinVar: uncertain significance; called by muse, varscan2
- DSCAML1 | c.335C>T p.S112F (on ENST00000321322; = p.S52F on NM_020693.4) | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.576); catalogued as rs928553789, COSV100356410; called by muse, mutect2, varscan2
- ELANE | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 372/727 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs942026381, COSV52255108; called by muse, mutect2, varscan2
- FBXW5 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 421/870 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1049209140; called by muse, mutect2, varscan2
- FILIP1L | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 161/346 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58772272; called by muse, varscan2
- GMEB1 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 61/488 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1485077792; called by muse, mutect2, varscan2
- GP5 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 378/787 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs779182714, COSV55461458; called by muse, varscan2
- HMCN1 | c.15914G>A p.R5305Q | Missense Mutation (SNP) | VAF 191/474 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs566532561, COSV54936856; called by muse, mutect2, varscan2
- IKBKE | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 277/548 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1174339324; called by muse, mutect2, varscan2
- KDM2B | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 359/718 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as rs545617761; called by muse, mutect2, varscan2
- LAMA5 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 253/564 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs374668224; called by muse, mutect2, varscan2
- LGI1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 250/506 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs751825973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXL3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 91/670 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766420467, COSV51206261; called by muse, mutect2, varscan2
- MAP1A | c.7672C>T p.H2558Y | Missense Mutation (SNP) | VAF 271/503 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1249216407; called by muse, mutect2, varscan2
- NOVA1 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 72/598 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as rs752004813, COSV99946777; called by muse, mutect2, varscan2
- NRK | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1166798144, COSV54589199; called by muse, mutect2, varscan2
- OBSL1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 219/504 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772619686; called by muse, mutect2, varscan2
- OCA2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 281/620 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs148468031, COSV62345033; called by muse, mutect2, varscan2
- OR5M11 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 146/377 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1327328349; called by muse, mutect2, varscan2
- PCDHAC1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 295/587 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1554205406, COSV53850316; called by muse, mutect2, varscan2
- PGBD5 | c.365G>A p.G122E (on ENST00000525115; = p.G191E on NM_001258311.2) | Missense Mutation (SNP) | VAF 306/636 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.305); catalogued as COSV100358350, COSV58410348; called by muse, mutect2, varscan2
- PHOX2B | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 313/585 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1289168625; called by muse, varscan2
- PLCL1 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 191/406 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV70823668; called by muse, mutect2, varscan2
- PLEKHA5 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 171/171 reads (100%) | catalogued as rs768578225; called by muse, mutect2, varscan2
- POTEG | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 176/1742 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377563534; called by muse, mutect2, varscan2
- PURG | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 226/458 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767466974, COSV53296113; called by muse, mutect2, varscan2
- RAB4B | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 238/505 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771504169, COSV63825912; called by muse, mutect2, varscan2
- RIPOR2 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.777); catalogued as rs369634523; called by muse, mutect2, varscan2
- RUBCNL | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 135/265 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs746370327; called by muse, mutect2, varscan2
- SAFB2 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 377/760 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV53045597; called by muse, mutect2, varscan2
- SLC6A5 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 460/936 reads (49%) | catalogued as COSV100117248; called by muse, mutect2
- SPATA16 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 228/457 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs374316672, COSV100651228; called by mutect2, varscan2
- SPTA1 | c.3697G>A p.V1233I | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs369125471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.1258C>T p.R420W (on ENST00000355995 / NM_001367943.1; = p.R397W on NM_030756.5) | Missense Mutation (SNP) | VAF 216/460 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53335898; called by muse, mutect2, varscan2
- TIAM1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 316/623 reads (51%) | catalogued as COSV54569911; called by muse, mutect2, varscan2
- TNN | c.2543G>A p.S848N | Missense Mutation (SNP) | VAF 172/590 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1383490442, COSV53436435; called by muse, mutect2, varscan2
- TNRC18 | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 347/770 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1445931484, COSV68168370; called by muse, mutect2
- TRPM5 | c.3088_3090del p.K1030del | In Frame Del (DEL) | VAF 297/596 reads (50%) | catalogued as rs749584595; called by pindel, varscan2
- TTC26 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 31/356 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs1167773215, COSV100571240; called by muse, mutect2
- TTN | c.98668_98670del p.K32890del (on ENST00000591111; = p.K25466del on NM_003319.4) | In Frame Del (DEL) | VAF 214/470 reads (46%) | catalogued as rs775651385; called by pindel, varscan2
- VPS13D | c.12538G>A p.G4180S | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs552663711, COSV50633290, COSV99167778; called by muse, mutect2, varscan2
- ZNF770 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 169/346 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1360743154; called by muse, mutect2, varscan2
- ZNF99 | c.2557C>A p.L853I | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747884760; called by muse, mutect2, varscan2
- ADHFE1 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AQR | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 104/230 reads (45%) | called by muse, mutect2
- ASCC1 | c.626C>T p.T209I (on ENST00000342444 / NM_001369085.1; = p.T181I on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/476 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN2 | c.1214C>A p.A405E (on ENST00000313400 / NM_001365069.1; = p.A354E on NM_014010.5) | Missense Mutation (SNP) | VAF 215/438 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- BRWD1 | c.6742C>G p.L2248V | Missense Mutation (SNP) | VAF 248/499 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC177 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 324/622 reads (52%) | called by muse, varscan2
- CEP290 | c.6232C>G p.Q2078E | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- COL22A1 | c.2397G>T p.E799D | Missense Mutation (SNP) | VAF 234/465 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTNNB1 | c.496-1G>A p.X166_splice | Splice Site (SNP) | VAF 158/320 reads (49%) | called by muse, mutect2, varscan2
- DIAPH1 | c.2486A>G p.K829R | Missense Mutation (SNP) | VAF 175/349 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLGAP4 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 676/1275 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FAM47B | c.1636A>G p.I546V | Missense Mutation (SNP) | VAF 210/851 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM71E2 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 330/696 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.3041C>T p.P1014L (on ENST00000354552 / NM_182909.3; = p.P774L on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/451 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FILIP1L | c.2858C>G p.S953C (on ENST00000354552 / NM_182909.3; = p.S713C on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 266/557 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FILIP1L | c.2555C>A p.S852Y (on ENST00000354552 / NM_182909.3; = p.S612Y on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/374 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.216); called by mutect2, varscan2
- FILIP1L | c.2021C>G p.S674C (on ENST00000354552 / NM_182909.3; = p.S434C on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/478 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FILIP1L | c.1568C>G p.S523C (on ENST00000354552 / NM_182909.3; = p.S283C on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/414 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FZD5 | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 307/681 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- IGLJ3 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 57/1482 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2
- IL17RC | c.2362G>A p.G788R (on ENST00000295981 / NM_153461.4; = p.G702R on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/534 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- LRRC6 | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 251/526 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MCM4 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 315/681 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MCM6 | c.985dup p.M329Nfs*11 | Frame Shift Ins (INS) | VAF 222/545 reads (41%) | called by mutect2, pindel, varscan2
- MCOLN3 | c.1021T>A p.W341R | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED1 | c.3155C>G p.P1052R | Missense Mutation (SNP) | VAF 250/493 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB8 | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 377/795 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PI4K2B | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 263/525 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PID1 | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 214/451 reads (47%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIWIL1 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 224/462 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 188/418 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- RBM15B | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 423/813 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RBMX | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 282/921 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC5A12 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 219/458 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A3 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 263/542 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- SLIT2 | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 196/445 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- SPG21 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 190/433 reads (44%) | called by muse, mutect2, varscan2
- SRCAP | c.6283G>A p.V2095I | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUPT16H | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 187/389 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TRIM71 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 338/714 reads (47%) | called by muse, mutect2, varscan2
- TTC6 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 146/317 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- USP31 | c.1261_1275del p.H421_G425del | In Frame Del (DEL) | VAF 87/297 reads (29%) | called by mutect2, pindel, varscan2
- USP5 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFYVE26 | c.6341A>G p.E2114G | Missense Mutation (SNP) | VAF 215/492 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- A3GALT2 | c.492G>A p.A164= | Silent (SNP) | VAF 342/642 reads (53%) | catalogued as COSV57760510; called by muse, mutect2, varscan2
- ADRA1B | c.1128C>A p.R376= | Silent (SNP) | VAF 191/362 reads (53%) | catalogued as rs1561612939, COSV100140557; called by muse, varscan2
- ANKLE1 | c.1443C>T p.D481= (on ENST00000394458; = p.D427= on NM_152363.6) | Silent (SNP) | VAF 200/469 reads (43%) | catalogued as rs780570496; called by muse, mutect2, varscan2
- AQR | c.1953A>G p.E651= | Silent (SNP) | VAF 98/221 reads (44%) | catalogued as rs764630106; called by muse, mutect2
- ARHGAP45 | c.843C>T p.G281= | Silent (SNP) | VAF 304/644 reads (47%) | catalogued as COSV57434120; called by muse, mutect2, varscan2
- CACHD1 | c.1425T>C p.F475= | Silent (SNP) | VAF 212/446 reads (48%) | catalogued as COSV51554837; called by muse, mutect2, varscan2
- CYTH3 | c.678C>T p.N226= | Silent (SNP) | VAF 205/503 reads (41%) | catalogued as rs1430762569; called by muse, mutect2, varscan2
- DCHS1 | c.9621C>T p.A3207= | Silent (SNP) | VAF 394/840 reads (47%) | called by muse, mutect2, varscan2
- EMB | c.6C>T p.R2= | Silent (SNP) | VAF 204/435 reads (47%) | catalogued as rs1488747782; called by muse, mutect2, varscan2
- KDM7A | c.2787T>G p.L929= | Silent (SNP) | VAF 32/774 reads (4%) | called by muse, mutect2
- MROH5 | c.3405C>T p.D1135= | Silent (SNP) | VAF 245/563 reads (44%) | catalogued as rs745949383, COSV61471520; called by muse, mutect2, varscan2
- MUC16 | c.18162C>T p.S6054= | Silent (SNP) | VAF 298/583 reads (51%) | catalogued as rs771724187; called by muse, mutect2, varscan2
- PCDHA5 | c.1626G>A p.P542= | Silent (SNP) | VAF 539/1076 reads (50%) | catalogued as rs782672816, COSV65349020; called by muse, mutect2, varscan2
- PHOX2A | c.63C>T p.Y21= | Silent (SNP) | VAF 333/691 reads (48%) | catalogued as rs777850396; called by muse, mutect2, varscan2
- PKD1 | c.957G>T p.P319= | Silent (SNP) | VAF 384/806 reads (48%) | catalogued as COSV99238357; called by mutect2, varscan2
- PTX4 | c.846C>T p.N282= (on ENST00000447419 / NM_001328608.2; = p.N277= on NM_001013658.1) | Silent (SNP) | VAF 278/612 reads (45%) | catalogued as rs1413742520; called by muse, mutect2
- REN | c.978C>T p.N326= | Silent (SNP) | VAF 161/375 reads (43%) | catalogued as rs144517174; called by muse, mutect2, varscan2
- SHISAL2B | c.225C>T p.A75= | Silent (SNP) | VAF 227/523 reads (43%) | called by muse, mutect2, varscan2
- SPATA22 | c.156T>C p.F52= | Silent (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- TANC2 | c.1047C>T p.H349= | Silent (SNP) | VAF 237/496 reads (48%) | catalogued as rs770637490; called by muse, mutect2, varscan2
- TBC1D8 | c.1641C>T p.T547= | Silent (SNP) | VAF 75/610 reads (12%) | catalogued as COSV65215598; called by muse, mutect2, varscan2
- TNXB | c.8952G>A p.P2984= (on ENST00000647633; = p.P2737= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 309/311 reads (99%) | catalogued as rs758889891; called by muse, mutect2, varscan2
- UGT8 | c.285T>C p.S95= | Silent (SNP) | VAF 260/528 reads (49%) | called by muse, mutect2, varscan2
- AC244258.1 | n.457G>T | RNA (SNP) | VAF 82/179 reads (46%) | catalogued as rs765810268; called by muse, mutect2, varscan2
- ACTN2 | c.784-500G>T | Intron (SNP) | VAF 179/383 reads (47%) | called by muse, mutect2, varscan2
- ATXN7 | c.*41dup | 3'UTR (INS) | VAF 217/544 reads (40%) | called by mutect2, pindel, varscan2
- HHIP | c.831+81T>G | Intron (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- PLEKHJ1 | chr19:2230344 del CCTGAGCGC | 3'Flank (DEL) | VAF 358/877 reads (41%) | called by mutect2, pindel, varscan2
- PXN | c.934-71C>T | Intron (SNP) | VAF 280/555 reads (50%) | called by muse, mutect2, varscan2
